Gene-level copy-number profile of tumor specimen AP-DMUM-NP from APOLLO case AP-DMUM, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Invasive mucinous adenocarcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3.
Specimen AP-DMUM-NP: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 827f54e3-6ca6-459b-8f90-eef00cd05679.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-DMUM-WA (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/0c04b02d-b990-4be4-95be-78b19237add3

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 528; copy number 2: 1,237; copy number 3: 9,326; copy number 4: 12,349; copy number 5: 10,514; copy number 6: 12,273; copy number 7: 6,057; copy number 8: 3,109; copy number 9: 593; copy number 10: 1,826; copy number 11: 327; copy number 12: 341; copy number 13: 22; copy number 14: 49; copy number 16: 91; copy number 17: 156; copy number 18: 11; copy number 20: 10; copy number 21: 1; copy number 22: 4; copy number 27: 3; copy number 29: 5; copy number 33: 2; copy number 34: 11; copy number 36: 12; copy number 39: 3; copy number 42: 14; copy number 43: 25; copy number 48: 2; copy number 55: 4.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:4,117,925–4,150,421, 3 genes: AC116562.1, OR7E103P, UNC93B4.
- chr17:18,415,728–18,551,705, 13 genes (within-gene range 0–5): KRT17P5, YWHAEP2, KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 425 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:15,564,170–15,744,339, 4 genes, copy number 13: AC008278.2, DDX1, AC008278.1, LINC01804.
- chr2:87,125,198–87,222,488, 3 genes, copy number 13: AC083899.1, MIR4771-1, CENPNP1.
- chr5:25,087,450–45,895,970, 289 genes, copy number 13–17 (broad region; genes not listed).
- chr8:126,325,454–128,564,679, 33 genes, copy number 20–39: AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824.
- chr12:1,791,963–2,697,950, 19 genes, copy number 14: CACNA2D4, AC005343.7, LRTM2, AC005342.2, LINC00940, DCP1B, CACNA1C, AC005342.1, CACNA1C-IT1, CACNA1C-IT2, AC005344.1, CACNA1C-AS4, CACNA1C-IT3, AC005293.1, AC005414.1, CACNA1C-AS3, AC007618.1, CACNA1C-AS2, CACNA1C-AS1.
- chr15:21,951,242–22,126,434, 11 genes, copy number 18: MIR5701-3, OR11J6P, AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P, OR4H6P, OR4M2, OR4N4, OR4N3P.
- chr17:44,353,215–44,389,649, 3 genes, copy number 13: FAM171A2, RPL7L1P5, ITGA2B.
- chr19:28,294,093–30,016,612, 39 genes, copy number 27–55: AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32.
- chr19:33,067,175–33,927,625, 24 genes, copy number 22–42: AC008521.2, GPATCH1, WDR88, LRP3, AC008738.1, AC008738.7, SLC7A10, AC008738.4, AC008738.6, AC008738.3, CEBPA, AC008738.5, CEBPA-DT, AC008738.2, RPS3AP50, AKR1B1P7, CEBPG, PEPD, AC010485.1, RPL21P131, CHST8, KCTD15, AC008556.1, RN7SL150P.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
